MMRF case MMRF_1348 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8b150be2-76c9-40c9-a5c1-7f11b2f28613

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.8 years (25,126 days); ISS stage: I; Days to last known disease status: 274 days; Days to last follow up: 274 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 56.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.907 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 0.26 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 92 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 0.29 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 11.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 8.42 mmol/L.
- Day 183 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 6.26 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 0.28 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.
- Day 274 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 8.46 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 0.3 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 7.87 mmol/L.

Other clinical attributes
- Day 1: Weight: 108 kg; Height: 183 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1348_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1348_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
